Somatic mutation profile of tumor specimen TCGA-56-8622-01A (aliquot TCGA-56-8622-01A-11D-2395-08) from TCGA case TCGA-56-8622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.1 years (24,861 days).
Specimen TCGA-56-8622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdad2591-1910-4d17-b253-15537146cc3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8622-10A (Blood Derived Normal), aliquot TCGA-56-8622-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a428656b-1605-412d-9991-86be79586df0

The open-access MAF lists 243 somatic variants for this specimen: 173 protein-altering or splice-affecting, 62 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 62, Nonsense Mutation 11, Frame Shift Del 6, Intron 4, Splice Region 3, Frame Shift Ins 3, Splice Site 2, Nonstop Mutation 2, RNA 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs121912673, CM980030, COSV51757858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99221046; called by muse, mutect2, varscan2
- ABCA12 | c.4717C>T p.H1573Y (on ENST00000272895 / NM_173076.3; = p.H1255Y on NM_015657.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55960458; called by muse, mutect2, varscan2
- ACSM3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99184274; called by muse, mutect2, varscan2
- ADAMTS12 | c.1774A>T p.N592Y | Missense Mutation (SNP) | VAF 175/234 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100710620; called by muse, mutect2, varscan2
- AGA | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs925345330, COSV52805940; called by muse, mutect2, varscan2
- AIPL1 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs770330369, COSV100006026; called by muse, mutect2, varscan2
- ANAPC2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100118983; called by muse, mutect2, varscan2
- ANKRD11 | c.2489A>G p.K830R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99968927; called by muse, mutect2, varscan2
- ARHGAP24 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67838072; called by muse, mutect2, varscan2
- ARHGEF6 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99166416; called by muse, mutect2, varscan2
- ASB13 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100731346, COSV63091321; called by muse, mutect2, varscan2
- ATP5MF | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs140907891, COSV99461669; called by muse, mutect2, varscan2
- BAZ2B | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100600524; called by muse, mutect2, varscan2
- BMP4 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99816856; called by muse, mutect2, varscan2
- BRDT | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1390595393, COSV62864718; called by muse, mutect2, varscan2
- BRINP3 | c.1032G>C p.L344F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.111); catalogued as COSV100818623, COSV100818936; called by muse, mutect2, varscan2
- C3 | c.4520G>A p.R1507H | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551187980, COSV55569804; called by muse, mutect2, varscan2
- C5 | c.3401C>T p.P1134L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV99797590; called by muse, mutect2, varscan2
- CACNA1S | c.4228G>T p.D1410Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754873; called by muse, mutect2, varscan2
- CC2D1A | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs746607724, COSV100528397; called by muse, mutect2, varscan2
- CD1C | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV100939374, COSV63806574; called by muse, mutect2, varscan2
- CEACAM5 | c.1494G>A p.A498= | Splice Region (SNP) | VAF 63/278 reads (23%) | catalogued as rs376406178; called by muse, mutect2, varscan2
- CELF2 | c.354G>A p.M118I (on ENST00000416382 / NM_001025077.3; = p.M125I on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100257190; called by muse, mutect2, varscan2
- CEP170 | c.1994A>T p.Q665L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100316813; called by muse, mutect2, varscan2
- CEP44 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99639359; called by muse, mutect2, varscan2
- CFAP46 | c.6125C>A p.A2042E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99584421; called by muse, mutect2, varscan2
- CHML | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100087237; called by muse, mutect2, varscan2
- CLSTN3 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs1378067647, COSV56936838; called by muse, mutect2, varscan2
- CNTNAP2 | c.1033G>C p.V345L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100664821; called by muse, mutect2, varscan2
- COL11A2 | c.3165del p.I1056Lfs*289 (on ENST00000341947 / NM_080680.3; = p.I949Lfs*289 on NM_080679.2) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV100553260; called by mutect2, pindel, varscan2
- CPA6 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99913222; called by muse, mutect2, varscan2
- CTNNA2 | c.2293C>A p.Q765K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV100559967, COSV100561884; called by muse, mutect2, varscan2
- CYB5R4 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100859654; called by muse, mutect2, varscan2
- CYLD | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV100282346; called by muse, mutect2, varscan2
- CYP2D6 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369390846; called by muse, mutect2, varscan2
- CYSLTR2 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56165994, COSV99935295; called by muse, mutect2, varscan2
- DDIT4L | c.226T>A p.S76T | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.336); catalogued as COSV56767003, COSV99913866; called by muse, mutect2
- DIDO1 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as rs757809856, COSV56632002, COSV99825403; called by muse, mutect2, varscan2
- DLGAP1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100229366, COSV59805693; called by muse, mutect2, varscan2
- DLX6 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142267; called by muse, mutect2, varscan2
- DNAH8 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100544275; called by muse, mutect2, varscan2
- DNAJC6 | c.1529G>T p.S510I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99674493; called by muse, mutect2, varscan2
- DPYSL4 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778250223, COSV58306254; called by muse, mutect2, varscan2
- DRP2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs766073418, COSV101235182; called by muse, varscan2
- EBF1 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565576; called by muse, mutect2, varscan2
- ELAPOR2 | c.1199C>A p.P400H (on ENST00000450689 / NM_001142749.3; = p.P233H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99788565; called by muse, mutect2, varscan2
- EPHA3 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV60709316, COSV60723061; called by muse, mutect2
- EPRS1 | c.4075G>T p.E1359* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100859354, COSV99055352; called by muse, mutect2, varscan2
- ERRFI1 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770998621, COSV101088048; called by muse, mutect2, varscan2
- FAM155B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs1307749411, COSV52935460; called by muse, mutect2, varscan2
- FAM47A | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100649810; called by muse, mutect2, varscan2
- FAT1 | c.10327G>T p.G3443* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as rs762740944, COSV101499256; called by muse, mutect2, varscan2
- FBN3 | c.4730del p.G1577Vfs*72 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as COSV54462674; called by mutect2, pindel, varscan2
- FBXO4 | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.197); catalogued as COSV99715114; called by muse, mutect2, varscan2
- FFAR4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as rs1398947747, COSV101015673; called by muse, mutect2, varscan2
- FGF10 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV99240383; called by muse, mutect2, varscan2
- FNDC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201109407; called by muse, varscan2
- GABRG2 | c.1061C>T p.T354I (on ENST00000361925 / NM_001375343.1; = p.T314I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100729638, COSV62717595; called by muse, mutect2, varscan2
- GLDC | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV100394001; called by muse, varscan2
- GPCPD1 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100980140; called by muse, mutect2, varscan2
- GPR158 | c.3648G>T p.*1216Yext*16 | Nonstop Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100893201; called by muse, mutect2, varscan2
- GPR82 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1569421423, COSV100220569; called by muse, mutect2, varscan2
- GRID2 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs745635313, COSV99939417, COSV99948298; called by muse, mutect2, varscan2
- GXYLT1 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.068); catalogued as rs1208835028, COSV99788152; called by muse, mutect2, varscan2
- HDAC6 | c.3586C>G p.L1196V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100490729; called by muse, mutect2, varscan2
- HESX1 | c.556T>A p.*186Kext*4 | Nonstop Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99907701; called by muse, mutect2
- IMPA2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV99302499; called by muse, mutect2, varscan2
- IPO7 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100797809; called by muse, varscan2
- ITSN1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV101180470; called by muse, mutect2, varscan2
- KALRN | c.1553A>G p.Q518R | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs950358380, COSV99563378; called by muse, mutect2, varscan2
- KCNK3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs549923058, COSV57192632; called by muse, mutect2, varscan2
- KIF23 | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99532190; called by muse, mutect2, varscan2
- KIRREL3 | c.2331C>A p.H777Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV101375171, COSV101375186; called by muse, mutect2, varscan2
- LAMA1 | c.1952A>C p.K651T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.601); catalogued as COSV101055838; called by muse, mutect2, varscan2
- LAP3 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99884202; called by muse, mutect2, varscan2
- LIN7C | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99536149; called by muse, mutect2, varscan2
- LMAN2 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100288319; called by muse, mutect2, varscan2
- LRFN2 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100599391; called by muse, mutect2, varscan2
- LRP1B | c.12115G>T p.G4039W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101255041; called by muse, mutect2, varscan2
- LRP2 | c.12461G>A p.R4154K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as COSV99787584; called by mutect2, varscan2
- LRRN3 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV100069364; called by muse, mutect2, varscan2
- MAST2 | c.1121G>C p.R374P | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100788001, COSV100788592; called by muse, mutect2, varscan2
- MCM3 | c.292G>C p.D98H (on ENST00000229854 / NM_001366374.2; = p.D88H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.929); catalogued as COSV100008721; called by muse, mutect2, varscan2
- MEP1B | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369048823; called by muse, mutect2, varscan2
- MMP17 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV100861894; called by muse, mutect2, varscan2
- MON1B | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 75/258 reads (29%) | catalogued as COSV99941643; called by muse, mutect2, varscan2
- MS4A10 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV100382263; called by muse, mutect2, varscan2
- MTR | c.3122A>G p.Q1041R | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100855321; called by muse, mutect2, varscan2
- MUC16 | c.6352G>A p.A2118T | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749152513, COSV67455691; called by muse, mutect2, varscan2
- MUC16 | c.702T>G p.Y234* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101199322; called by muse, mutect2, varscan2
- MYBPC1 | c.2014G>C p.D672H (on ENST00000550270 / NM_206820.2; = p.D697H on NM_002465.4) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100637877, COSV62251424; called by muse, mutect2
- MYO15A | c.9883C>T p.R3295C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775389608, COSV52755815; called by muse, mutect2, varscan2
- MYO3A | c.783T>G p.N261K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99779144; called by muse, mutect2, varscan2
- MYO3A | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV56318243, COSV99779145; called by muse, mutect2, varscan2
- MYT1 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100114383; called by muse, mutect2, varscan2
- NAT1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.195); catalogued as COSV56986747; called by muse, mutect2, varscan2
- NCKAP5L | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV100258597; called by muse, mutect2, varscan2
- NDUFAF7 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs758365105, COSV99135491; called by muse, mutect2, varscan2
- NIBAN1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100836359; called by muse, mutect2
- NOTCH1 | c.4532C>T p.S1511L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV53053838; called by muse, mutect2
- NPAP1 | c.2408C>G p.T803S | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.136); catalogued as COSV100275089; called by muse, mutect2, varscan2
- NPHS2 | c.741T>G p.V247= | Splice Region (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100858145; called by muse, mutect2, varscan2
- NTNG1 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.083); catalogued as COSV53976849, COSV99636510; called by muse, mutect2, varscan2
- OR1C1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552057368, COSV68715664; called by muse, mutect2, varscan2
- OR1I1 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.232); catalogued as COSV99264764; called by muse, mutect2, varscan2
- OR2AK2 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823388; called by muse, mutect2, varscan2
- OR2L13 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as rs752563868, COSV100813718; called by muse, mutect2, varscan2
- OR4B1 | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100535553; called by muse, mutect2, varscan2
- OR4C15 | c.583G>T p.G195C (on ENST00000314644; = p.G141C on NM_001001920.2) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.132); catalogued as rs201504039, COSV100115556, COSV100115675; called by muse, mutect2, varscan2
- OR4C46 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs777097476, COSV60219182, COSV60221186; called by muse, mutect2, varscan2
- OR52L1 | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as COSV100176123; called by muse, mutect2, varscan2
- ORAI3 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931527677, COSV100590914, COSV100590940; called by muse, mutect2, varscan2
- PARP15 | c.1939T>C p.F647L (on ENST00000464300 / NM_001113523.3; = p.F413L on NM_152615.2) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1016862112, COSV100117048; called by muse, mutect2, varscan2
- PBRM1 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99968212; called by muse, mutect2, varscan2
- PEG3 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs200424391; called by muse, mutect2, varscan2
- PHF21A | c.1225-2A>T p.X409_splice (on ENST00000418153 / NM_001101802.3; = p.X410_splice on NM_016621.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99138330; called by muse, mutect2, varscan2
- PIGV | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1376564813, COSV99314870; called by muse, mutect2, varscan2
- PPM1A | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100348961, COSV57786430; called by muse, mutect2, varscan2
- PTPN6 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV59687023; called by muse, mutect2, varscan2
- PTPRC | c.3081G>T p.W1027C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722428; called by muse, mutect2, varscan2
- RASAL1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99921593; called by muse, mutect2, varscan2
- RASAL1 | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99921594; called by muse, mutect2, varscan2
- RIPK2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99609829; called by muse, mutect2, varscan2
- RNF6 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100644617; called by muse, mutect2, varscan2
- RTL4 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100465836, COSV100466023; called by muse, mutect2, varscan2
- RTN4 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1320485549, COSV100462961; called by muse, mutect2, varscan2
- SAMD9 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV101180179; called by muse, mutect2, varscan2
- SCPEP1 | c.1107_1108insT p.L370Sfs*24 | Frame Shift Ins (INS) | VAF 24/121 reads (20%) | catalogued as COSV99227768; called by mutect2, pindel, varscan2
- SHROOM3 | c.1545T>G p.D515E | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV99933998; called by muse, mutect2, varscan2
- SLC22A8 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV100267819; called by muse, mutect2, varscan2
- SLC30A8 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101438328; called by muse, mutect2, varscan2
- SLC44A3 | c.276A>G p.K92= (on ENST00000271227 / NM_001114106.3; = p.K44= on NM_152369.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 28/115 reads (24%) | catalogued as COSV99598004; called by muse, mutect2, varscan2
- SLC8A1 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1357557301, COSV60477993; called by muse, mutect2, varscan2
- SORCS2 | c.3418A>G p.N1140D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.34); catalogued as COSV100212225; called by muse, mutect2, varscan2
- SOX14 | c.645dup p.V216Rfs*34 | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | catalogued as rs779768969; called by mutect2, pindel, varscan2
- SPOCK3 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.998); catalogued as COSV100692750; called by muse, mutect2, varscan2
- SRGAP1 | c.2246T>C p.I749T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as rs1360392260, COSV100754492; called by muse, mutect2, varscan2
- SYCP1 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101050833; called by muse, mutect2, varscan2
- SYT9 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.428); catalogued as COSV100607884; called by muse, mutect2, varscan2
- TFAP2D | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV99145832; called by muse, mutect2
- TIMM22 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.123); catalogued as rs1004257510, COSV100215048; called by muse, mutect2, varscan2
- TMEM132B | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100169156; called by muse, mutect2, varscan2
- TMEM63C | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100029328; called by muse, mutect2, varscan2
- TNFRSF10B | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV99375307; called by muse, mutect2, varscan2
- TNNT1 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52570400, COSV99402803; called by muse, mutect2
- TPTE | c.767G>T p.R256M (on ENST00000618007 / NM_199261.4; = p.R238M on NM_199259.4) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs751839881; called by muse, mutect2
- TRPA1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100082825, COSV100083748; called by muse, mutect2, varscan2
- TSHZ2 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV100295798; called by muse, mutect2, varscan2
- TTN | c.69917G>C p.R23306P (on ENST00000591111; = p.R15882P on NM_003319.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | PolyPhen possibly damaging (0.706); catalogued as COSV100604375, COSV60015763; called by muse, mutect2, varscan2
- UACA | c.2906C>G p.A969G | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV100537433; called by muse, mutect2, varscan2
- UBR4 | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100920665; called by muse, mutect2
- UNC13C | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV99514859; called by muse, mutect2, varscan2
- VAX2 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs376990356, COSV52266393; called by muse, mutect2, varscan2
- VRTN | c.870C>A p.S290R | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs767258652, COSV56439609, COSV99832193; called by muse, mutect2, varscan2
- WDR7 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99589158; called by muse, mutect2, varscan2
- YARS1 | c.1477-1G>A p.X493_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99614444; called by muse, mutect2, varscan2
- ZNF200 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV101205224; called by muse, mutect2, varscan2
- ZNF200 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101205226; called by muse, mutect2
- ZNF200 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV101205229; called by muse, mutect2, varscan2
- ZNF236 | c.3902C>G p.S1301C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99470002; called by muse, mutect2, varscan2
- ZNF275 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100936204; called by muse, mutect2, varscan2
- ZNF28 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as rs750118883, COSV100354403; called by muse, mutect2, varscan2
- ZNF404 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs942947991, COSV100182468; called by muse, mutect2, varscan2
- ZNF99 | c.1683del p.K562Rfs*52 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as COSV68056371; called by mutect2, pindel, varscan2
- ACACA | c.6124G>T p.D2042Y | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHD8 | c.2264_2265dup p.Y756Pfs*9 (on ENST00000646647 / NM_001170629.2; = p.Y477Pfs*9 on NM_020920.4) | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- NRXN3 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR13C4 | c.191del p.G64Afs*20 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- OR4E2 | c.217del p.H73Tfs*15 | Frame Shift Del (DEL) | VAF 58/230 reads (25%) | called by mutect2, pindel, varscan2
- SPPL2C | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2
- TRBV29-1 | c.252C>G p.S84R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZFHX4 | c.1201del p.M401Cfs*6 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2691G>C p.L897= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV101001572; called by muse, mutect2, varscan2
- ADCY6 | c.801C>T p.L267= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1174068155, COSV100326557; called by muse, mutect2, varscan2
- AHCTF1 | c.1788G>A p.L596= (on ENST00000366508; = p.L570= on NM_015446.5) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100403459, COSV58251596; called by muse, mutect2, varscan2
- ALDH16A1 | c.1296C>T p.S432= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs957495847, COSV99512769; called by muse, mutect2, varscan2
- AOC1 | c.786C>A p.V262= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100710721; called by muse, mutect2, varscan2
- ARMC6 | c.1257G>A p.Q419= (on ENST00000392336; = p.Q394= on NM_033415.4) | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV99522997; called by mutect2, varscan2
- ATP10D | c.3036G>T p.L1012= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV99905449; called by muse, mutect2, varscan2
- BRINP1 | c.1407G>A p.E469= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99775057; called by muse, mutect2, varscan2
- CARD11 | c.1524G>A p.Q508= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100829053, COSV100829130; called by muse, mutect2
- CD3D | c.513G>A p.K171= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV100329358; called by muse, mutect2, varscan2
- CD84 | c.624C>G p.A208= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100245935, COSV60869521; called by muse, mutect2, varscan2
- CHRD | c.1017A>T p.L339= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99200331; called by muse, mutect2, varscan2
- CNGB3 | c.1530C>A p.L510= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100181489; called by muse, mutect2, varscan2
- CNOT1 | c.624G>A p.K208= | Silent (SNP) | VAF 58/270 reads (21%) | catalogued as rs1213811703, COSV100408987; called by muse, mutect2, varscan2
- COL6A6 | c.1272G>T p.T424= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100650131; called by muse, mutect2
- CRK | c.225C>A p.P75= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100315587; called by muse, mutect2, varscan2
- CYP24A1 | c.1083T>C p.P361= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs147886742; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCAF13 | c.810A>G p.A270= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99885184; called by muse, mutect2, varscan2
- DCDC1 | c.5334G>T p.L1778= (on ENST00000597505 / NM_001367979.1; = p.L885= on NM_020869.3) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100360421; called by muse, mutect2
- DCP1B | c.9C>G p.A3= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs200127830, COSV99767405; called by muse, mutect2, varscan2
- DLX6 | c.684G>A p.Q228= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV99142264; called by muse, mutect2, varscan2
- EIF3E | c.699T>C p.I233= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV99623014; called by muse, mutect2, varscan2
- EPHA10 | c.2571G>A p.K857= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100361183; called by muse, mutect2, varscan2
- EPHA3 | c.1347C>A p.S449= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV100344331; called by muse, mutect2, varscan2
- ERRFI1 | c.1092G>T p.L364= | Silent (SNP) | VAF 42/312 reads (13%) | catalogued as COSV101088047; called by muse, mutect2, varscan2
- FAM76B | c.777T>G p.L259= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100716426; called by muse, varscan2
- FBXL16 | c.315C>A p.L105= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100178878; called by muse, mutect2, varscan2
- GABRA2 | c.915C>A p.P305= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100734079; called by muse, mutect2, varscan2
- GPR153 | c.912G>T p.R304= | Silent (SNP) | VAF 147/251 reads (59%) | catalogued as COSV100928492; called by muse, mutect2, varscan2
- HCAR3 | c.285T>C p.F95= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs1221026656, COSV100811554; called by muse, mutect2, varscan2
- HERC5 | c.717A>T p.G239= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99987590; called by muse, mutect2, varscan2
- IDI1 | c.483G>A p.V161= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as rs1380582661, COSV101191184; called by muse, mutect2
- IQCC | c.1299A>C p.P433= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99356474; called by muse, mutect2, varscan2
- KIAA1586 | c.369A>G p.S123= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1562570404, COSV100875335; called by muse, mutect2, varscan2
- KLHL30 | c.519G>A p.Q173= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100014202; called by muse, mutect2, varscan2
- KRT78 | c.717G>A p.L239= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs770499154, COSV58850916; called by muse, mutect2, varscan2
- MED24 | c.1488C>T p.S496= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs749117410, COSV100673099; called by muse, mutect2, varscan2
- MMP16 | c.309A>C p.V103= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV99687180, COSV99687215; called by muse, mutect2, varscan2
- MOB2 | c.315A>G p.P105= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100326498; called by muse, mutect2, varscan2
- MUC16 | c.15096C>T p.P5032= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV101199321; called by muse, mutect2, varscan2
- MUC5B | c.7902C>T p.I2634= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as COSV101500220; called by muse, mutect2
- MYH7 | c.1725C>T p.A575= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs1399862230, COSV100805936; called by muse, mutect2, varscan2
- NAV3 | c.4626A>G p.E1542= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs1263608256, COSV99889248; called by muse, mutect2, varscan2
- NSMCE4A | c.1008A>G p.E336= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100940044; called by muse, mutect2, varscan2
- OR51G2 | c.30C>T p.S10= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100432097; called by muse, mutect2, varscan2
- OR6C65 | c.888A>G p.K296= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV65569624; called by muse, mutect2, varscan2
- PDZD2 | c.8064G>A p.L2688= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV99224552; called by muse, mutect2
- PDZD8 | c.2622T>C p.Y874= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs761658470, COSV100041525; called by muse, mutect2, varscan2
- PGC | c.195C>A p.P65= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100756951; called by muse, mutect2, varscan2
- PSME4 | c.1452G>A p.L484= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs776295316, COSV101122413; called by muse, mutect2, varscan2
- RSPH4A | c.1084C>T p.L362= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99994067; called by muse, mutect2, varscan2
- RYR2 | c.3270C>A p.A1090= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100769331, COSV100769353; called by muse, mutect2, varscan2
- SAFB | c.2652G>T p.R884= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as COSV99412676; called by muse, mutect2, varscan2
- SIGLEC6 | c.597G>A p.V199= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV100585282; called by muse, mutect2, varscan2
- SLITRK6 | c.1377T>G p.P459= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV101233208; called by muse, mutect2, varscan2
- TMEM9 | c.84G>T p.R28= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs751625026, COSV100947362; called by muse, mutect2, varscan2
- TNFAIP1 | c.408C>T p.N136= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV99880257; called by muse, mutect2, varscan2
- TTN | c.25524C>T p.S8508= (on ENST00000591111; = p.S7581= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs774217877, COSV60097950; called by muse, mutect2, varscan2
- WASF1 | c.621G>T p.L207= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99661143; called by muse, mutect2, varscan2
- ZIC3 | c.858T>C p.H286= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99798717; called by muse, mutect2, varscan2
- ZNF200 | c.747G>A p.R249= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101205228; called by muse, mutect2
- ZNF804B | c.1873C>T p.L625= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100302926; called by muse, mutect2
- AL162726.3 | n.255+83428G>T | Intron (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850970 C>A | 3'Flank (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-28G>T | 5'UTR (SNP) | VAF 34/272 reads (13%) | catalogued as COSV99801846; called by muse, mutect2, varscan2
- C5orf64 | n.512+51903T>G | Intron (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- SNORD115-25 | n.28C>G | RNA (SNP) | VAF 81/374 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.12097del | RNA (DEL) | VAF 10/45 reads (22%) | catalogued as COSV100948020; called by mutect2, pindel, varscan2
- TNK2 | c.-18-6691G>C | Intron (SNP) | VAF 11/100 reads (11%) | catalogued as COSV100361165; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-564G>A | Intron (SNP) | VAF 26/154 reads (17%) | catalogued as COSV100514298; called by muse, mutect2, varscan2
